Somatic mutation profile of tumor specimen 0DWNTS from CCDI case PBCNMR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,251 days).
Specimen 0DWNTS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a471f46e-725e-4142-bfc2-c2c8b1f85735.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNQY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b63369f6-e607-48f7-8c86-04640f45a626

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HIPK3 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 21/633 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV57564468; called by muse, mutect2
- TFAP2C | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 19/730 reads (3%) | catalogued as rs1359138714, COSV99571330; called by muse, mutect2
- AMMECR1L | c.441C>T p.D147= | Silent (SNP) | VAF 194/566 reads (34%) | called by muse, mutect2, varscan2
- OMA1 | c.1443G>A p.T481= | Silent (SNP) | VAF 28/608 reads (5%) | catalogued as rs778242651, COSV62253773; called by muse, mutect2
